Gene-level copy-number profile of tumor specimen TCGA-24-1564-01A from TCGA case TCGA-24-1564, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.5 years (24,668 days).
Specimen TCGA-24-1564-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.eaf70996-ac08-4e56-8747-06a8af702dd5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1564-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0086a65a-3d6c-4c30-848b-9ed52eeb77e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 2,620; copy number 2: 26,449; copy number 3: 18,189; copy number 4: 6,245; copy number 5: 4,433; copy number 6: 1,133; copy number 7: 505; copy number 8: 12; copy number 9: 67; copy number 11: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1564-01A-01D-0497-01): tumor purity 0.41, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:14,404,551–15,330,282, 34 genes (within-gene range 0–2): AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,219 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,809,574–43,456,995, 187 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:91,949,371–193,254,815, 1,998 genes, copy number 5–11 (broad region; genes not listed).
- chr1:193,473,224–194,198,708, 1 gene, copy number 5 (within-gene range 3–5): AL136456.1.
- chr1:194,188,967–248,919,946, 1,193 genes, copy number 5 (broad region; genes not listed).
- chr3:84,958,989–86,991,149, 12 genes, copy number 8 (within-gene range 4–8): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3.
- chr6:41,101,022–45,377,953, 149 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:47,231,532–49,877,096, 39 genes, copy number 5 (within-gene range 3–5): TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1, FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1.
- chr8:65,155,407–145,066,685, 1,254 genes, copy number 5 (broad region; genes not listed).
- chr10:628,638–38,783,108, 665 genes, copy number 6 (broad region; genes not listed).
- chr11:4,094,707–6,185,576, 145 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:47,778,087–50,422,316, 87 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:1,344,275–4,143,030, 126 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:6,628,619–7,711,372, 104 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:13,095,695–13,100,939, 1 gene, copy number 5: AC005303.1.
- chr17:13,494,032–14,069,495, 7 genes, copy number 5 (within-gene range 1–5): HS3ST3A1, MIR548H3, COX10-AS1, AC005304.2, AC005304.1, AC005304.3, CDRT15P1.
- chr20:44,436,172–53,741,797, 251 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
